CCDI case PBCJXK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/6aa0c50d-3036-40ed-9441-fafd98c55f12

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 3.0 years (1,090 days).

Biospecimens (3 samples)
- Sample 0DV98M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV994: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DV99M: Tissue type: Tumor; Specimen type: Solid Tissue.
